TCGA case TCGA-EL-A3CZ — Thyroid Carcinoma (TCGA-THCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Thyroid gland; Tissue source site: MD Anderson. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c951b786-7de3-4195-85b9-c4c19e95f546

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 37 years; Vital status: Alive.

Diagnoses (2)
1. Papillary adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8260/3; ICD-10 code: C73; Tissue or organ of origin: Thyroid gland; Site of resection or biopsy: Thyroid gland; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 37.6 years (13,718 days); Year of diagnosis: 2007; AJCC staging edition: 6th; AJCC pathologic T: T1; AJCC pathologic N: N1a; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Days to last follow up: 2,418 days (6.6 years); Tumor focality: Unifocal.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 7; Measurement unit: Centimeters; Tumor depth measurement: 2; Tumor length measurement: 4.5; Tumor width measurement: 3.
   Treatment given: Treatment type: Radiation, Systemic; Days to treatment start: 157 days; Treatment dose: 100 mCi; Number of fractions: 1; Treatment anatomic sites: Regional Site.
   Recorded as not given: adjuvant I-131 Radiation Therapy; adjuvant Pharmaceutical Therapy, NOS.
2. Recurrence of diagnosis 1 (Papillary adenocarcinoma, NOS), site: Lymph node, NOS. Age at diagnosis: 41.5 years (15,144 days); Days to diagnosis: 1,426 days (3.9 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 2,382 days (6.5 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.

Follow-up (5 entries)
- Day 1,426 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Lymph node, NOS; Days to recurrence: 1,426 days (3.9 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 1,606 days (4.4 years); Disease response: Tumor Free.
- Days to follow up: 1,788 days (4.9 years); Disease response: With Tumor.
- Days to follow up: 2,418 days (6.6 years); Disease response: With Tumor.
- Imaging type: MRI; Imaging anatomic site: Lymph Node; Timepoint: Preoperative.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-EL-A3CZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 240 mg.
  Slide TCGA-EL-A3CZ-01A-01-TSA: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-EL-A3CZ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-EL-A3CZ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; History radiation exposure: No; Submitted tumor site: Thyroid; Histologic diagnosis: Thyroid Papillary Carcinoma - Classical/usual; Laterality: Left lobe; Lymph nodes preop imaging: Yes; Lymph nodes examined: Yes.
- Neoplasm dimension: Tumor size width: 3.0; Tumor size width: 2.0.
- Lymph node preoperative assessment diagnostic imaging types: Lymph nodes preop imaging type: MRI with contrast.
- Follow-up form 1: Lost to follow-up: No; Tumor status: With tumor; I 131 radiation first treatment method: Patient did not receive I-131 treatment.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,418 days; disease-specific survival: no event (censored), 2,418 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,426 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-EL-A3CZ-01A-11D-A19I-01): tumor purity 0.55, ploidy 2, whole-genome doublings 0.
